Somatic mutation profile of tumor specimen TCGA-CW-6090-01A (aliquot TCGA-CW-6090-01A-11D-1669-08) from TCGA case TCGA-CW-6090, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 68.2 years (24,909 days).
Specimen TCGA-CW-6090-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54640c31-414e-4555-9a19-5ebd2ed811e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CW-6090-11A (Solid Tissue Normal), aliquot TCGA-CW-6090-11A-01D-1669-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/631e5242-7d6a-4e9d-9a47-9987ce09a6f3

The open-access MAF lists 117 somatic variants for this specimen: 80 protein-altering or splice-affecting, 33 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 33, Nonsense Mutation 6, Frame Shift Del 6, Frame Shift Ins 5, In Frame Del 4, RNA 2, 5'UTR 1, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABLIM3 | c.576G>T p.K192N | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58644527; called by muse, mutect2, varscan2
- ADGRF5 | c.2098A>C p.I700L | Missense Mutation (SNP) | VAF 73/205 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV51935317; called by muse, mutect2, varscan2
- AGO4 | c.2524C>T p.Q842* | Nonsense Mutation (SNP) | VAF 36/103 reads (35%) | catalogued as COSV64617461; called by muse, mutect2, varscan2
- AKIP1 | c.566T>G p.L189* | Nonsense Mutation (SNP) | VAF 90/265 reads (34%) | catalogued as COSV55149135; called by muse, mutect2, varscan2
- ANXA10 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV63739245; called by muse, mutect2, varscan2
- ARHGDIB | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV57456200; called by muse, mutect2, varscan2
- BBS9 | c.1099C>G p.Q367E | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.352); catalogued as COSV54172256; called by muse, mutect2, varscan2
- BTNL3 | c.559A>C p.S187R | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV61565061; called by muse, mutect2, varscan2
- CELSR1 | c.5779G>A p.G1927S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs758214473, COSV53092428; called by muse, mutect2, varscan2
- CIITA | c.841C>G p.P281A | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as COSV60858567; called by muse, mutect2, varscan2
- CILP | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV56025039; called by muse, mutect2, varscan2
- CLCA4 | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs971981455, COSV55368790; called by muse, mutect2, varscan2
- CNGB3 | c.1985T>A p.L662H | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as COSV60691525; called by muse, varscan2
- CNOT11 | c.1137A>G p.I379M | Missense Mutation (SNP) | VAF 81/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56820190; called by muse, mutect2, varscan2
- CYP4A11 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as COSV60223980; called by mutect2, varscan2
- EDRF1 | c.3450A>C p.E1150D (on ENST00000356792 / NM_001202438.2; = p.E1116D on NM_015608.2) | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.291); catalogued as COSV61764440; called by muse, mutect2, varscan2
- F13B | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.049); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FGFR1 | c.1885G>C p.V629L (on ENST00000447712 / NM_023110.3; = p.V627L on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58327304, COSV58336545; called by muse, mutect2, varscan2
- GAREM1 | c.1139C>T p.T380I | Missense Mutation (SNP) | VAF 40/91 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52511073; called by muse, mutect2, varscan2
- GJB3 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as COSV64904668; called by muse, mutect2, varscan2
- GPT | c.1419dup p.E475Gfs*72 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | catalogued as rs776744432; called by mutect2, varscan2
- HRH4 | c.392A>G p.K131R | Missense Mutation (SNP) | VAF 59/188 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV56928400; called by muse, mutect2, varscan2
- JCAD | c.2430C>G p.C810W | Missense Mutation (SNP) | VAF 41/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64760153; called by muse, mutect2, varscan2
- KIAA0100 | c.1515T>C p.G505= | Splice Region (SNP) | VAF 16/79 reads (20%) | catalogued as COSV66493826; called by muse, mutect2, varscan2
- LCE1B | c.182G>C p.G61A | Missense Mutation (SNP) | VAF 111/186 reads (60%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.099); catalogued as COSV63980384, COSV99080910; called by muse, mutect2, varscan2
- LMO4 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV65170387; called by muse, mutect2, varscan2
- MAGED2 | c.1528G>C p.E510Q | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV54498265; called by muse, mutect2, varscan2
- MCC | c.744G>A p.M248I | Missense Mutation (SNP) | VAF 67/173 reads (39%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.708); catalogued as COSV56730400; called by muse, mutect2, varscan2
- MS4A14 | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.069); catalogued as rs555925241, COSV55735573; called by muse, mutect2, varscan2
- MTNR1B | c.68C>A p.S23* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV57066868, COSV57068891; called by muse, mutect2
- MYO16 | c.3949G>A p.A1317T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs764112051, COSV62751895; called by muse, mutect2
- MYO5C | c.238G>T p.E80* | Nonsense Mutation (SNP) | VAF 31/85 reads (36%) | catalogued as COSV55907650, COSV55910922; called by muse, mutect2, varscan2
- MYRF | c.844G>A p.V282M (on ENST00000278836 / NM_001127392.3; = p.V273M on NM_013279.4) | Missense Mutation (SNP) | VAF 78/252 reads (31%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs367694531, COSV53887227; called by muse, mutect2, varscan2
- NAGK | c.434G>C p.G145A | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54903841; called by muse, mutect2, varscan2
- NPHP1 | c.814C>A p.L272I | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); catalogued as COSV57209348; called by muse, mutect2, varscan2
- OAZ3 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58618416; called by muse, mutect2, varscan2
- OR10T2 | c.841G>C p.V281L | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as COSV57781750; called by muse, mutect2, varscan2
- PDE4A | c.1845G>C p.Q615H (on ENST00000380702 / NM_001111307.2; = p.Q376H on NM_006202.3) | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as COSV53357291; called by muse, mutect2, varscan2
- POPDC2 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs557421349, COSV51741530; called by muse, mutect2, varscan2
- PPP2R2B | c.1204G>T p.D402Y (on ENST00000394409; = p.D468Y on NM_181674.2) | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.805); catalogued as COSV60767796; called by muse, mutect2, varscan2
- PRDM1 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs1562174876, COSV64844363; called by muse, mutect2, varscan2
- QDPR | c.266G>A p.G89E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1463441963, COSV55550705; called by muse, mutect2, varscan2
- RP1 | c.6079G>A p.D2027N | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV55118911; called by muse, mutect2, varscan2
- RREB1 | c.1048G>A p.A350T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs899514750, COSV58559506; called by muse, mutect2, varscan2
- RUVBL2 | c.374G>C p.R125P | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as COSV55485712; called by muse, mutect2, varscan2
- RYR1 | c.12118G>A p.A4040T | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs374441925; called by muse, mutect2, varscan2
- SCAI | c.1562C>T p.S521L (on ENST00000336505 / NM_001144877.3; = p.S544L on NM_173690.5) | Missense Mutation (SNP) | VAF 133/234 reads (57%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.966); catalogued as COSV57176109; called by muse, mutect2, varscan2
- SEL1L3 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.704); catalogued as COSV53542951; called by muse, mutect2, varscan2
- SEPTIN14 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756494333, COSV101193413, COSV66428354; called by muse, mutect2, varscan2
- SETD5 | c.2398C>A p.P800T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.031); catalogued as rs1304539619, COSV56712743; called by muse, mutect2, varscan2
- SHC2 | c.1429C>A p.P477T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.031); catalogued as COSV52746865; called by muse, mutect2, varscan2
- SLC17A6 | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 84/235 reads (36%) | catalogued as COSV54137486, COSV54137776; called by muse, mutect2, varscan2
- SLITRK5 | c.2006G>A p.S669N | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV61523516; called by muse, mutect2, varscan2
- SNRPN | c.67G>T p.D23Y | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57597619; called by muse, mutect2, varscan2
- SOX4 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.918); catalogued as COSV55193324; called by muse, varscan2
- SPSB3 | c.721G>C p.G241R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51601153; called by muse, mutect2, varscan2
- SPTAN1 | c.283A>T p.N95Y | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as COSV63987814; called by muse, mutect2, varscan2
- ST6GALNAC1 | c.403A>G p.N135D | Missense Mutation (SNP) | VAF 79/213 reads (37%) | PolyPhen benign (0); catalogued as COSV50075510; called by muse, mutect2, varscan2
- SYNJ1 | c.1355A>C p.E452A | Missense Mutation (SNP) | VAF 63/166 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV59150132; called by muse, mutect2, varscan2
- TMEM131L | c.918A>G p.I306M | Missense Mutation (SNP) | VAF 69/168 reads (41%) | SIFT tolerated (0.55); PolyPhen benign (0.078); catalogued as COSV53645776; called by muse, mutect2, varscan2
- TMTC3 | c.2003C>G p.A668G | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.117); catalogued as COSV57124416; called by muse, mutect2, varscan2
- USH2A | c.9565G>A p.A3189T | Missense Mutation (SNP) | VAF 123/196 reads (63%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as CM149232, COSV56384333; called by muse, mutect2, varscan2
- VHL | c.535dup p.D179Gfs*77 | Frame Shift Ins (INS) | VAF 14/35 reads (40%) | catalogued as CI984223, COSV56568511; called by mutect2, pindel, varscan2
- VLDLR | c.2463T>A p.N821K | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV66077954; called by muse, mutect2, varscan2
- ZC3H18 | c.2231C>T p.S744F | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1402853827, COSV56325482; called by muse, mutect2, varscan2
- ZNF276 | c.1669G>C p.D557H (on ENST00000443381 / NM_001113525.2; = p.D482H on NM_152287.4) | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57069350; called by muse, mutect2, varscan2
- ZNF546 | c.1361C>T p.T454M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as rs1357821896, COSV61258202; called by muse, mutect2, varscan2
- AKR1B1 | c.414del p.L139Wfs*16 | Frame Shift Del (DEL) | VAF 91/307 reads (30%) | called by mutect2, pindel, varscan2
- EID3 | c.614dup p.L205Ffs*8 | Frame Shift Ins (INS) | VAF 23/90 reads (26%) | called by mutect2, pindel, varscan2
- GID8 | c.635_638del p.K212Ifs*4 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | called by mutect2, pindel, varscan2
- GLI1 | c.2076_2093del p.I692_A697del | In Frame Del (DEL) | VAF 17/130 reads (13%) | called by mutect2, pindel, varscan2
- PITPNM2 | c.343_345del p.Y115del | In Frame Del (DEL) | VAF 128/366 reads (35%) | called by mutect2, pindel, varscan2
- PLB1 | c.331del p.S111Qfs*39 | Frame Shift Del (DEL) | VAF 17/80 reads (21%) | called by mutect2, pindel, varscan2
- PRPF8 | c.5624_5629del p.H1875_L1876del | In Frame Del (DEL) | VAF 24/68 reads (35%) | called by mutect2, pindel, varscan2
- PTGR2 | c.104del p.N35Mfs*22 | Frame Shift Del (DEL) | VAF 29/90 reads (32%) | called by mutect2, pindel, varscan2
- SAPCD1 | c.296dup p.L100Vfs*17 | Frame Shift Ins (INS) | VAF 16/143 reads (11%) | called by mutect2, pindel, varscan2
- SLC6A3 | c.266_269dup p.Y91Vfs*107 | Frame Shift Ins (INS) | VAF 40/166 reads (24%) | called by pindel, varscan2
- SP8 | c.524del p.I175Tfs*84 (on ENST00000361443 / NM_198956.4; = p.I193Tfs*84 on NM_182700.6) | Frame Shift Del (DEL) | VAF 5/13 reads (38%) | called by mutect2, varscan2
- TMX2 | c.429del p.D143Efs*8 | Frame Shift Del (DEL) | VAF 71/250 reads (28%) | called by mutect2, pindel, varscan2
- ZNF397 | c.381_387delinsA p.D127_L128del | In Frame Del (DEL) | VAF 23/75 reads (31%) | called by pindel, varscan2*
- ABHD17C | c.945A>G p.L315= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51917901; called by muse, mutect2, varscan2
- AC013489.1 | c.1602G>A p.R534= | Silent (SNP) | VAF 44/110 reads (40%) | catalogued as COSV51551816; called by muse, varscan2
- ACVR1 | c.1341A>G p.V447= | Silent (SNP) | VAF 74/249 reads (30%) | catalogued as rs756877324, COSV55119649; called by muse, mutect2, varscan2
- CLPB | c.1725G>A p.E575= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as COSV53630558; called by muse, mutect2, varscan2
- COLEC12 | c.669G>T p.L223= | Silent (SNP) | VAF 71/184 reads (39%) | catalogued as COSV68371320; called by muse, mutect2, varscan2
- CP | c.489A>G p.E163= | Silent (SNP) | VAF 32/149 reads (21%) | catalogued as COSV52831214; called by muse, mutect2, varscan2
- DNAJC25-GNG10 | c.454T>C p.L152= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as COSV65349853; called by muse, mutect2, varscan2
- DOT1L | c.1404G>A p.Q468= | Silent (SNP) | VAF 20/149 reads (13%) | catalogued as rs769111582, COSV67110468; called by muse, mutect2, varscan2
- EML2 | c.1491C>T p.S497= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV55600518; called by muse, mutect2, varscan2
- GPHN | c.126C>T p.L42= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs751833125, COSV59477192; called by muse, mutect2, varscan2
- ITGAE | c.1425C>G p.S475= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53995352, COSV54001595, COSV99561609; called by muse, mutect2, varscan2
- LARP1B | c.654T>C p.Y218= | Silent (SNP) | VAF 64/156 reads (41%) | catalogued as rs1199410632, COSV52798704; called by muse, mutect2
- MAGEE1 | c.468C>T p.A156= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV63910588; called by muse, mutect2, varscan2
- MAP1B | c.5709C>A p.G1903= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV57100727; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1653C>T p.P551= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as rs533033002, COSV53798172; called by muse, mutect2, varscan2
- MUC16 | c.42270A>G p.P14090= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV66693245; called by muse, mutect2, varscan2
- NCOR2 | c.3375C>T p.I1125= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as rs756684433, COSV62299406; called by muse, mutect2, varscan2
- NTNG2 | c.976C>A p.R326= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV62367302; called by muse, mutect2, varscan2
- PAFAH1B1 | c.678T>C p.C226= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as CM094800, COSV68210316; called by mutect2, varscan2
- PHB2 | c.183C>T p.D61= | Silent (SNP) | VAF 61/187 reads (33%) | catalogued as rs1555151810, COSV54642345; called by muse, mutect2, varscan2
- PIP4K2C | c.1176C>G p.V392= | Silent (SNP) | VAF 24/74 reads (32%) | catalogued as COSV61606433; called by muse, mutect2, varscan2
- PTPRU | c.348C>T p.T116= | Silent (SNP) | VAF 56/253 reads (22%) | catalogued as COSV60529748; called by muse, mutect2, varscan2
- RCC2 | c.714C>T p.N238= | Silent (SNP) | VAF 67/163 reads (41%) | catalogued as rs762579861, COSV64905966; called by muse, mutect2, varscan2
- RHCG | c.759C>T p.T253= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as COSV51515451; called by muse, mutect2, varscan2
- RSAD2 | c.414G>A p.K138= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as COSV65908438; called by muse, mutect2, varscan2
- SHANK1 | c.957C>T p.H319= | Silent (SNP) | VAF 58/172 reads (34%) | catalogued as COSV53247281; called by muse, mutect2, varscan2
- SLC26A11 | c.1002C>T p.Y334= | Silent (SNP) | VAF 51/185 reads (28%) | catalogued as COSV63279851; called by muse, mutect2, varscan2
- SLC38A2 | c.423A>G p.A141= | Silent (SNP) | VAF 65/194 reads (34%) | catalogued as COSV56745338; called by muse, mutect2, varscan2
- SYNGR1 | c.525C>G p.G175= | Silent (SNP) | VAF 23/84 reads (27%) | catalogued as COSV59560175; called by muse, mutect2, varscan2
- TDRD6 | c.4254C>T p.C1418= | Silent (SNP) | VAF 85/480 reads (18%) | catalogued as COSV60176414; called by muse, mutect2, varscan2
- THAP2 | c.117T>G p.V39= | Silent (SNP) | VAF 38/119 reads (32%) | catalogued as rs1009735381, COSV57348948; called by muse, mutect2, varscan2
- UTP4 | c.1692C>T p.S564= | Silent (SNP) | VAF 28/79 reads (35%) | catalogued as COSV58733304; called by muse, mutect2, varscan2
- ZMYND10 | c.693G>A p.R231= | Silent (SNP) | VAF 20/40 reads (50%) | catalogued as COSV51602361; called by muse, mutect2, varscan2
- GCNT2 | c.926-34712del | Intron (DEL) | VAF 49/124 reads (40%) | called by mutect2, pindel, varscan2
- RBM8A | c.-2A>T | 5'UTR (SNP) | VAF 24/35 reads (69%) | catalogued as COSV100355325; called by muse, mutect2, varscan2
- SNORD88C | n.14G>A | RNA (SNP) | VAF 6/18 reads (33%) | called by muse, mutect2
- ZNF658B | n.2302C>G | RNA (SNP) | VAF 52/105 reads (50%) | called by mutect2, varscan2
